Somatic mutation profile of tumor specimen ALCH-B2M3-TTP1-A (aliquot ALCH-B2M3-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2M3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 74.5 years (27,220 days).
Specimen ALCH-B2M3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff85c59a-b460-4854-8ab3-8dbae6b6f10a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2M3-NB1-A (Blood Derived Normal), aliquot ALCH-B2M3-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17d48ce9-3c53-4514-a410-fedf21faf60d

The open-access MAF lists 1,227 somatic variants for this specimen: 832 protein-altering or splice-affecting, 248 silent, 147 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 691, Silent 248, Intron 72, Nonsense Mutation 59, RNA 33, Splice Site 27, Frame Shift Del 24, 3'UTR 15, 5'Flank 13, Splice Region 12, Frame Shift Ins 12, 5'UTR 10.

Variants (750 of 1,227; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT16 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 362/1098 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as rs59856285, CM148379, CM148380, CM950726, COSV56969059, COSV56969755; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 114/149 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.2326G>T p.D776Y | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV100383180; called by muse, mutect2, varscan2
- ABCB1 | c.2590A>G p.I864V | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as rs539556127, COSV55947359; called by muse, mutect2, varscan2
- ABCB5 | c.2349G>T p.W783C (on ENST00000404938 / NM_001163941.2; = p.W338C on NM_178559.6) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV99033882; called by muse, mutect2, varscan2
- ABHD17A | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 53/494 reads (11%) | catalogued as COSV51749806; called by muse, varscan2
- AC008397.2 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 85/125 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1232413842; called by muse, mutect2, varscan2
- ACADM | c.119-2A>G p.X40_splice | Splice Site (SNP) | VAF 80/219 reads (37%) | catalogued as rs1376804614, COSV100897699; called by muse, mutect2, varscan2
- ACTL9 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.891); catalogued as COSV100185484; called by muse, mutect2, varscan2
- ACVR2A | c.191G>T p.W64L | Missense Mutation (SNP) | VAF 93/165 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54022571; called by muse, mutect2, varscan2
- ADCY1 | c.3023G>T p.R1008L | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52036386; called by muse, varscan2
- ADGRG4 | c.3848C>A p.S1283Y | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs377239456, COSV54957590, COSV54966049; called by muse, mutect2, varscan2
- AGMO | c.905C>A p.P302Q | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751893917, COSV61111511; called by muse, varscan2
- AGO3 | c.1988C>T p.T663I | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.481); catalogued as rs1261569146; called by muse, mutect2, varscan2
- AIFM2 | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV57159352; called by muse, mutect2, varscan2
- AL031777.2 | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 202/699 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs746957898; called by muse, mutect2, varscan2
- ALG10B | c.1381del p.Q461Sfs*28 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | catalogued as COSV100439854; called by mutect2, varscan2
- ANHX | c.31C>A p.H11N | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1220784469; called by muse, mutect2, varscan2
- ANK2 | c.10690G>A p.D3564N | Missense Mutation (SNP) | VAF 87/344 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV52179474; called by muse, varscan2
- ANKRD35 | c.2405G>T p.G802V | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV100841724; called by muse, mutect2, varscan2
- AP2A2 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1324980532; called by muse, mutect2, varscan2
- AP3B1 | c.2089G>T p.G697* | Nonsense Mutation (SNP) | VAF 14/103 reads (14%) | catalogued as COSV99672460; called by muse, mutect2, varscan2
- ARID2 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100536463; called by muse, mutect2, varscan2
- ARID2 | c.5002C>G p.L1668V | Missense Mutation (SNP) | VAF 97/244 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV57617309; called by muse, mutect2, varscan2
- BRCA2 | c.7327G>A p.D2443N | Missense Mutation (SNP) | VAF 122/157 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1460835970; called by muse, varscan2
- BRD9 | c.1580C>T p.T527M | Missense Mutation (SNP) | VAF 114/208 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs1356964265, COSV60246591; called by muse, mutect2, varscan2
- BRINP1 | c.1697C>A p.P566H | Missense Mutation (SNP) | VAF 102/206 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56295346; called by muse, mutect2, varscan2
- BTBD11 | c.2422G>A p.V808M (on ENST00000280758 / NM_001018072.2; = p.V345M on NM_001017523.2) | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777874310; called by muse, mutect2, varscan2
- C4orf17 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.792); catalogued as COSV58512810; called by muse, mutect2, varscan2
- CACNA1I | c.5306C>T p.P1769L | Missense Mutation (SNP) | VAF 274/318 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs751904410; called by muse, mutect2, varscan2
- CALCR | c.668C>A p.P223H (on ENST00000649521 / NM_001164737.2; = p.P207H on NM_001742.4) | Missense Mutation (SNP) | VAF 60/76 reads (79%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.96); catalogued as COSV64012833; called by muse, mutect2, varscan2
- CCDC191 | c.161C>G p.S54* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as COSV99878614; called by muse, mutect2, varscan2
- CCDC33 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs182048903; called by muse, mutect2, varscan2
- CCDC85A | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs371781745; called by muse, mutect2, varscan2
- CCR1 | c.116del p.P39Lfs*27 | Frame Shift Del (DEL) | VAF 53/127 reads (42%) | catalogued as COSV99946592; called by mutect2, pindel, varscan2
- CDH7 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV59885547; called by muse, mutect2
- CDHR3 | c.2347G>C p.D783H | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58421489; called by muse, mutect2, varscan2
- CEACAM21 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 131/307 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs981984811, COSV51813353; called by muse, mutect2, varscan2
- CFAP70 | c.956T>A p.I319K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1263194769; called by muse, mutect2, varscan2
- CFHR1 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 240/596 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.613); catalogued as COSV57626247, COSV57626920, COSV57628831; called by muse, varscan2
- CHD5 | c.2865G>T p.M955I | Missense Mutation (SNP) | VAF 119/301 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs1557547746, COSV52411438; called by muse, mutect2, varscan2
- CHRNA1 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 174/337 reads (52%) | SIFT tolerated (1); PolyPhen probably damaging (0.963); catalogued as COSV53684392; called by muse, mutect2, varscan2
- CLCA4 | c.1171T>C p.Y391H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1356679631; called by muse, mutect2, varscan2
- CNR1 | c.1048del p.V350Wfs*3 | Frame Shift Del (DEL) | VAF 72/219 reads (33%) | catalogued as COSV62987821; called by pindel, varscan2
- CNTN1 | c.2916C>A p.Y972* | Nonsense Mutation (SNP) | VAF 11/328 reads (3%) | catalogued as COSV61640764; called by muse, mutect2
- COL15A1 | c.2334G>T p.R778S | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.307); catalogued as COSV66642972; called by muse, varscan2
- COL6A2 | c.1674G>A p.A558= | Splice Region (SNP) | VAF 50/205 reads (24%) | catalogued as rs144334894, COSV100153204; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL6A5 | c.1092G>T p.E364D | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.056); catalogued as COSV55212559; called by muse, mutect2, varscan2
- CPED1 | c.374C>A p.T125K | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.35); PolyPhen benign (0.138); catalogued as COSV60007111, COSV60010443; called by muse, mutect2, varscan2
- CREBBP | c.4805G>A p.R1602H | Missense Mutation (SNP) | VAF 285/770 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1274540523, COSV52140014, COSV99272523; called by muse, mutect2, varscan2
- CRYBA4 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 81/96 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs778397499, COSV100697877; called by muse, mutect2, varscan2
- CSMD3 | c.5689G>T p.G1897C (on ENST00000297405 / NM_001363185.1; = p.G1793C on NM_052900.3) | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52117997; called by muse, mutect2, varscan2
- CT47B1 | c.541G>C p.A181P | Missense Mutation (SNP) | VAF 279/326 reads (86%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.958); catalogued as COSV64890669; called by muse, mutect2, varscan2
- CTNND2 | c.2138G>T p.R713L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58886074; called by muse, mutect2, varscan2
- CUL5 | c.92G>C p.R31P | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.48); catalogued as COSV67609827; called by muse, mutect2, varscan2
- DACT1 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 176/352 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1255816484; called by muse, mutect2, varscan2
- DDX43 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 101/116 reads (87%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV64813800; called by muse, mutect2, varscan2
- DEFB124 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV58343641; called by muse, mutect2, varscan2
- DHX35 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99327279; called by muse, mutect2, varscan2
- DIRAS3 | c.177C>A p.S59R | Missense Mutation (SNP) | VAF 193/410 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63970762; called by muse, mutect2, varscan2
- DKK2 | c.467C>G p.S156* | Nonsense Mutation (SNP) | VAF 86/188 reads (46%) | catalogued as COSV53395716; called by muse, mutect2, varscan2
- DMD | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 62/83 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99918380; called by muse, mutect2, varscan2
- DNAH11 | c.5365G>C p.G1789R | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100181868; called by muse, mutect2, varscan2
- DOCK3 | c.4388G>T p.G1463V | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746570235; called by muse, mutect2, varscan2
- DSC2 | c.1595G>A p.S532N | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV51867093; called by muse, mutect2, varscan2
- DSCAM | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 98/342 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV68036570; called by muse, mutect2, varscan2
- DVL1 | c.1571del p.P524Rfs*150 (on ENST00000378888 / NM_001330311.2; = p.P499Rfs*150 on NM_004421.3) | Frame Shift Del (DEL) | VAF 63/165 reads (38%) | catalogued as COSV100229386; called by mutect2, pindel, varscan2
- DYSF | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 128/256 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV50518244; called by muse, varscan2
- EIF6 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 134/343 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as rs369629636; called by muse, mutect2, varscan2
- ELP4 | c.514-1G>C p.X172_splice | Splice Site (SNP) | VAF 45/122 reads (37%) | catalogued as COSV63352314; called by muse, mutect2, varscan2
- ENAH | c.599G>C p.R200P | Missense Mutation (SNP) | VAF 185/408 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.226); catalogued as COSV52870507; called by mutect2, varscan2
- FAM135B | c.708C>A p.H236Q | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs192537076, COSV52727002; called by muse, mutect2, varscan2
- FAM184B | c.2195C>G p.S732W | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99400710; called by muse, mutect2, varscan2
- FAM219A | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.997); catalogued as COSV99896582; called by muse, mutect2
- FAM47A | c.575C>G p.P192R | Missense Mutation (SNP) | VAF 88/103 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV60494955, COSV60498067; called by muse, mutect2, varscan2
- FAM47C | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 85/102 reads (83%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as COSV100792526; called by muse, mutect2, varscan2
- FAM91A1 | c.1861G>T p.D621Y | Missense Mutation (SNP) | VAF 101/249 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100593731; called by muse, mutect2, varscan2
- FBRSL1 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208490204; called by muse, mutect2, varscan2
- FEZ1 | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1216564086; called by muse, mutect2, varscan2
- FGF1 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61803619; called by muse, mutect2
- FGFR1 | c.570G>T p.W190C (on ENST00000447712 / NM_023110.3; = p.W188C on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/157 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as CM133685; called by muse, mutect2, varscan2
- FIBP | c.957G>T p.W319C (on ENST00000338369 / NM_198897.2; = p.W312C on NM_004214.5) | Missense Mutation (SNP) | VAF 91/237 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215789067; called by muse, mutect2, varscan2
- FLG | c.10291C>T p.Q3431* | Nonsense Mutation (SNP) | VAF 208/596 reads (35%) | catalogued as COSV100911484, COSV64247101; called by muse, mutect2, varscan2
- FOLR1 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 111/315 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as CM1311252, COSV56615963; called by muse, mutect2, varscan2
- FOXP1 | c.1424G>T p.R475M | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100562241; called by muse, mutect2, varscan2
- FPR2 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 84/204 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV60672310; called by muse, mutect2, varscan2
- FUT9 | c.757A>T p.I253F | Missense Mutation (SNP) | VAF 98/118 reads (83%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.614); catalogued as COSV56150399; called by muse, mutect2
- GABRG1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.142); catalogued as rs765534501, COSV54954723, COSV99777566; called by muse, varscan2
- GALNT14 | c.1638C>A p.H546Q | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.83); PolyPhen benign (0.017); catalogued as rs752251096, COSV61110382; called by muse, mutect2, varscan2
- GCN1 | c.3685G>T p.D1229Y | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56106445; called by muse, mutect2, varscan2
- GCNT1 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.723); catalogued as COSV65059298; called by muse, mutect2, varscan2
- GCSAML | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867795960, COSV63577305; called by muse, mutect2, varscan2
- GDNF | c.426T>A p.F142L | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58480712; called by muse, mutect2, varscan2
- GPKOW | c.809G>C p.R270P | Missense Mutation (SNP) | VAF 129/134 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99332668; called by muse, mutect2, varscan2
- GPR108 | c.582G>T p.L194F | Missense Mutation (SNP) | VAF 118/170 reads (69%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV51184933; called by muse, mutect2, varscan2
- GRIA1 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 37/176 reads (21%) | catalogued as COSV53617450, COSV53629433; called by muse, varscan2
- GUCY2F | c.1579C>A p.R527S | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV54308474; called by muse, mutect2, varscan2
- HHATL | c.1300A>G p.M434V | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1208547863; called by muse, mutect2, varscan2
- HMBS | c.99A>G p.I33M | Missense Mutation (SNP) | VAF 162/424 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs556420446; called by muse, mutect2, varscan2
- HTR1A | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 87/363 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs1454434636; called by muse, mutect2, varscan2
- HYAL4 | c.196A>T p.R66* | Nonsense Mutation (SNP) | VAF 44/57 reads (77%) | catalogued as COSV56139368; called by muse, mutect2, varscan2
- ICAM1 | c.55del p.A19Lfs*28 | Frame Shift Del (DEL) | VAF 86/156 reads (55%) | catalogued as COSV99321071; called by mutect2, pindel, varscan2
- IGHD | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 200/438 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as rs767340720; called by muse, mutect2, varscan2
- IL17RD | c.1071G>T p.K357N | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99577284; called by muse, mutect2, varscan2
- IL1RAPL1 | c.327G>T p.L109F | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV100151098; called by muse, mutect2, varscan2
- IL23R | c.1400C>A p.S467* | Nonsense Mutation (SNP) | VAF 37/111 reads (33%) | catalogued as COSV61372667; called by muse, mutect2, varscan2
- KALRN | c.7442C>A p.T2481N (on ENST00000360013 / NM_001024660.4; = p.T784N on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs745901858; called by muse, varscan2
- KCNA1 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 261/327 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66838908, COSV99059679; called by muse, mutect2, varscan2
- KCNH5 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV59757645; called by muse, mutect2, varscan2
- KCNK9 | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 382/973 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV57278730, COSV57285891; called by muse, mutect2, varscan2
- KIRREL2 | c.1715G>T p.R572L | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs199552023, COSV52876644; called by muse, mutect2, varscan2
- KLHL14 | c.982G>T p.G328* | Nonsense Mutation (SNP) | VAF 57/239 reads (24%) | catalogued as COSV63832801; called by muse, mutect2, varscan2
- KMT2C | c.8344G>T p.D2782Y | Missense Mutation (SNP) | VAF 57/78 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100070284; called by muse, mutect2, varscan2
- KRT13 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 195/351 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs1208867074; called by muse, mutect2, varscan2
- KRT78 | c.429G>T p.W143C | Missense Mutation (SNP) | VAF 140/349 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756539697, COSV100467163; called by muse, mutect2, varscan2
- KRTAP13-1 | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 146/337 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV62663184; called by muse, varscan2
- LPP | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.886); catalogued as rs777467972; called by muse, mutect2, varscan2
- LRIG3 | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as rs954036491, COSV57863327; called by muse, mutect2, varscan2
- LRP1 | c.4283G>C p.R1428P | Missense Mutation (SNP) | VAF 124/340 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV54504388, COSV54520495; called by muse, mutect2, varscan2
- LRP5 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 139/315 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53723020; called by muse, mutect2, varscan2
- MAP2 | c.4529G>T p.G1510V | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs569403800; called by muse, mutect2, varscan2
- MBOAT1 | c.152G>C p.R51P | Missense Mutation (SNP) | VAF 116/248 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756580004, COSV61124747, COSV61126356; called by muse, mutect2, varscan2
- MC2R | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 143/312 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.304); catalogued as COSV59620712; called by muse, mutect2, varscan2
- MDM1 | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 46/147 reads (31%) | catalogued as rs1240712010; called by muse, mutect2, varscan2
- MOXD1 | c.1195C>A p.L399M | Missense Mutation (SNP) | VAF 86/107 reads (80%) | SIFT tolerated (0.39); PolyPhen benign (0.142); catalogued as rs1315954476; called by muse, varscan2
- MPDZ | c.4019G>T p.R1340L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs374429110, COSV59916487; called by muse, mutect2, varscan2
- MROH2B | c.590G>C p.W197S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773256355, COSV68190106; called by muse, mutect2, varscan2
- MS4A14 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs766782093; called by muse, mutect2, varscan2
- MTCL1 | c.5506G>A p.D1836N (on ENST00000306329 / NM_001378206.1; = p.D1517N on NM_015210.4) | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769182692; called by muse, mutect2, varscan2
- MUC12 | c.16135G>C p.V5379L (on ENST00000379442; = p.V5236L on NM_001164462.1) | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0.03); catalogued as COSV59332129; called by muse, mutect2, varscan2
- MUC16 | c.6733G>T p.E2245* | Nonsense Mutation (SNP) | VAF 33/47 reads (70%) | catalogued as COSV101202109; called by muse, mutect2, varscan2
- MUC17 | c.1888A>G p.T630A | Missense Mutation (SNP) | VAF 58/78 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100073937; called by muse, varscan2
- MUC7 | c.353C>A p.S118* | Nonsense Mutation (SNP) | VAF 115/279 reads (41%) | catalogued as COSV59216987, COSV59219305; called by muse, mutect2, varscan2
- MYCN | c.173C>A p.T58K | Missense Mutation (SNP) | VAF 206/371 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55257982, COSV99808532; called by muse, mutect2, varscan2
- MYH11 | c.5528C>A p.S1843* | Nonsense Mutation (SNP) | VAF 245/615 reads (40%) | catalogued as COSV55556983; called by muse, mutect2, varscan2
- MYH7 | c.2714G>T p.C905F | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs730880757, CM032608, CM1412218; called by muse, mutect2, varscan2
- MYL2 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 118/252 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as CD130651; called by muse, mutect2, varscan2
- MYO16 | c.5257+1G>A p.X1753_splice | Splice Site (SNP) | VAF 27/90 reads (30%) | catalogued as rs1345650791; called by muse, mutect2, varscan2
- NDST2 | c.1920G>C p.E640D | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100014256; called by muse, mutect2, varscan2
- NGEF | c.1350G>A p.V450= | Splice Region (SNP) | VAF 52/224 reads (23%) | catalogued as rs182302282; called by muse, mutect2, varscan2
- NKG7 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as rs756059494; called by muse, mutect2, varscan2
- NLGN4X | c.2300C>G p.S767W | Missense Mutation (SNP) | VAF 95/130 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV52019787; called by muse, mutect2, varscan2
- NLRP4 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs372254857; called by muse, mutect2, varscan2
- NOBOX | c.1856C>A p.P619Q | Missense Mutation (SNP) | VAF 57/79 reads (72%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as CM152398; called by muse, mutect2, varscan2
- NOS1 | c.2023G>A p.G675R | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769211402, COSV100500249; called by muse, mutect2, varscan2
- NOS2 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as COSV58224013; called by muse, mutect2, varscan2
- NUDT14 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 162/380 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs777240882, COSV59650703; called by muse, mutect2, varscan2
- NWD2 | c.2556C>A p.Y852* | Nonsense Mutation (SNP) | VAF 39/147 reads (27%) | catalogued as COSV58750222; called by muse, mutect2, varscan2
- OR10Q1 | c.508C>A p.L170M | Missense Mutation (SNP) | VAF 208/534 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV57472283; called by muse, mutect2, varscan2
- OR13C9 | c.574A>T p.I192F | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV52242063; called by muse, mutect2, varscan2
- OR2G3 | c.300A>C p.Q100H | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV60682608; called by muse, mutect2, varscan2
- OR2L8 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 40/164 reads (24%) | catalogued as COSV61727837; called by muse, varscan2
- OR2L8 | c.922T>A p.C308S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV61728167; called by muse, varscan2
- OR2T3 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as rs965513390, COSV100613141; called by muse, mutect2, varscan2
- OR4P4 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs1251803516; called by muse, mutect2, varscan2
- OR51B4 | c.80T>C p.M27T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1309741929; called by muse, mutect2
- OR6C74 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs199782638; called by muse, mutect2, varscan2
- OR6F1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs370308508, COSV57467470; called by muse, mutect2, varscan2
- OR6Y1 | c.849C>A p.Y283* | Nonsense Mutation (SNP) | VAF 57/197 reads (29%) | catalogued as COSV56931595; called by muse, mutect2, varscan2
- PAPOLB | c.91G>T p.V31F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs758239625; called by muse, varscan2
- PCDHA12 | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 219/382 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56496267; called by muse, mutect2, varscan2
- PCDHA3 | c.1535C>A p.A512E | Missense Mutation (SNP) | VAF 929/1128 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV100793723, COSV63542265; called by muse, mutect2, varscan2
- PCDHB5 | c.2051C>A p.S684* | Nonsense Mutation (SNP) | VAF 163/624 reads (26%) | catalogued as COSV50647333; called by muse, varscan2
- PCDHB8 | c.813C>G p.D271E | Missense Mutation (SNP) | VAF 335/1250 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs781807195; called by muse, mutect2, varscan2
- PCDHGC4 | c.1613G>T p.R538L | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV52759774; called by muse, mutect2, varscan2
- PCM1 | c.4913G>A p.S1638N | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1178595357; called by muse, mutect2, varscan2
- PDE1C | c.682C>A p.H228N | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100372838, COSV58523494; called by muse, mutect2, varscan2
- PDE4B | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV100303991; called by muse, mutect2, varscan2
- PDP1 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 100/366 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as COSV99034349; called by muse, mutect2, varscan2
- PEG3 | c.4709G>C p.G1570A | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99687857; called by muse, mutect2, varscan2
- PER1 | c.2308C>A p.P770T | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs750597356; called by muse, mutect2, varscan2
- PEX5L | c.50T>A p.L17Q | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs766811023; called by muse, mutect2, varscan2
- PGGHG | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 288/775 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as rs780785433; called by muse, mutect2, varscan2
- PGK2 | c.648A>T p.K216N | Missense Mutation (SNP) | VAF 124/433 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59163681, COSV59165126; called by muse, mutect2, varscan2
- PHYHD1 | c.268G>T p.G90* | Nonsense Mutation (SNP) | VAF 95/190 reads (50%) | catalogued as rs746164646; called by muse, mutect2, varscan2
- PIAS2 | c.1613A>C p.H538P | Missense Mutation (SNP) | VAF 73/133 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV61343452; called by muse, mutect2, varscan2
- PKHD1L1 | c.11728G>A p.E3910K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV101006471, COSV65754506; called by muse, mutect2, varscan2
- PLEC | c.5893C>T p.R1965W (on ENST00000322810 / NM_201380.4; = p.R1855W on NM_000445.5) | Missense Mutation (SNP) | VAF 95/379 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1475632975, COSV59628446; called by muse, mutect2, varscan2
- POLD1 | c.1268G>T p.R423L | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70955418; called by muse, mutect2, varscan2
- PPFIA4 | c.2782-5G>A | Splice Region (SNP) | VAF 37/94 reads (39%) | catalogued as rs1192953722, COSV55317207; called by muse, mutect2, varscan2
- PPP4R3C | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 51/54 reads (94%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs1352196317; called by muse, mutect2, varscan2
- PRDM10 | c.928A>G p.T310A | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs1265007640, COSV100456899; called by muse, mutect2, varscan2
- PRDM12 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.309); catalogued as rs139266687; called by muse, mutect2
- PRKG1 | c.930G>T p.L310F | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1564452654; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRLH | c.154C>A p.R52S | Missense Mutation (SNP) | VAF 255/486 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138895198; called by muse, mutect2, varscan2
- PROX1 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 37/93 reads (40%) | catalogued as COSV99799166; called by muse, mutect2, varscan2
- PRSS56 | c.447C>A p.G149= | Splice Region (SNP) | VAF 25/79 reads (32%) | catalogued as COSV99285762; called by muse, mutect2, varscan2
- PSG6 | c.1144C>A p.Q382K | Missense Mutation (SNP) | VAF 142/363 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs1345906862, COSV51831255; called by muse, mutect2, varscan2
- PTPRD | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100643726, COSV61925879; called by mutect2, varscan2
- PXN | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 101/263 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs770650321, COSV57219437; called by muse, mutect2, varscan2
- RASA3 | c.354C>A p.D118E | Missense Mutation (SNP) | VAF 106/482 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV61869322; called by muse, mutect2, varscan2
- RBMXL3 | c.2995G>T p.D999Y | Missense Mutation (SNP) | VAF 81/96 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV57747936; called by muse, mutect2, varscan2
- RETNLB | c.244T>A p.C82S | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55465052; called by muse, mutect2, varscan2
- REXO1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 123/146 reads (84%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1273382259; called by muse, mutect2, varscan2
- RHPN2 | c.5C>A p.T2N | Missense Mutation (SNP) | VAF 87/426 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV54281929; called by muse, varscan2
- RIC3 | c.884C>G p.S295W (on ENST00000309737 / NM_001206671.4; = p.S294W on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs751315626; called by muse, mutect2, varscan2
- RIMBP2 | c.1094G>C p.R365P | Missense Mutation (SNP) | VAF 214/494 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55476838; called by muse, mutect2, varscan2
- RNF152 | c.254C>A p.S85Y | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV57184474; called by muse, mutect2, varscan2
- RPGRIP1 | c.3029G>C p.R1010T | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as COSV52844238, COSV99251220; called by muse, mutect2, varscan2
- RREB1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs766731211; called by muse, mutect2, varscan2
- RTL1 | c.2111C>A p.A704E | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1196286736; called by muse, mutect2, varscan2
- SAGE1 | c.337C>A p.R113S | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV61013152; called by muse, mutect2, varscan2
- SCN7A | c.4411G>C p.V1471L | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV69272469; called by muse, mutect2, varscan2
- SCN9A | c.1793G>T p.R598L | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); catalogued as COSV57598441; called by muse, mutect2, varscan2
- SDK2 | c.4733G>T p.R1578L | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs777693190, COSV101169023; called by muse, mutect2, varscan2
- SEMA6C | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.076); catalogued as rs1336790805; called by muse, mutect2, varscan2
- SERPINB11 | c.908C>A p.S303Y | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV66957718; called by muse, varscan2
- SIRPG | c.658G>T p.V220F | Missense Mutation (SNP) | VAF 124/256 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV99403594; called by muse, mutect2, varscan2
- SLC17A9 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 85/293 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV64848681; called by muse, mutect2, varscan2
- SLC24A2 | c.914C>A p.P305Q | Missense Mutation (SNP) | VAF 87/177 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99646760; called by muse, mutect2, varscan2
- SLC25A47 | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 238/640 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.316); catalogued as COSV100690081; called by muse, mutect2, varscan2
- SLC35A5 | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); catalogued as COSV53726221; called by muse, mutect2, varscan2
- SLC38A5 | c.740G>T p.C247F | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV58334475; called by muse, mutect2, varscan2
- SLC9A5 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs576356728, COSV55364336; called by muse, mutect2, varscan2
- SLC9C2 | c.2908-1G>T p.X970_splice | Splice Site (SNP) | VAF 68/224 reads (30%) | catalogued as COSV100876942; called by muse, mutect2, varscan2
- SMARCA4 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 116/160 reads (73%) | catalogued as rs760562676, COSV60790052; called by muse, mutect2, varscan2
- SNX22 | c.75+5G>A | Splice Region (SNP) | VAF 222/349 reads (64%) | catalogued as rs1302738971; called by muse, mutect2, varscan2
- SPEG | c.4149C>T p.G1383= | Splice Region (SNP) | VAF 42/185 reads (23%) | catalogued as COSV56676425; called by muse, mutect2, varscan2
- SPTBN2 | c.4649G>A p.R1550Q | Missense Mutation (SNP) | VAF 252/639 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs751384734; called by muse, mutect2, varscan2
- SQOR | c.865-1G>T p.X289_splice | Splice Site (SNP) | VAF 85/140 reads (61%) | catalogued as rs764246203; called by muse, mutect2, varscan2
- STXBP6 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1392186683; called by muse, mutect2, varscan2
- TBX19 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 96/252 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM121756; called by muse, mutect2, varscan2
- TFDP2 | c.1312G>A p.D438N (on ENST00000489671 / NM_001178139.2; = p.D378N on NM_006286.5) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as COSV100050589, COSV57704914; called by muse, mutect2
- TH | c.770C>A p.A257D (on ENST00000381178 / NM_199292.3; = p.A226D on NM_000360.4) | Missense Mutation (SNP) | VAF 130/342 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs1334929754; called by muse, mutect2, varscan2
- TLE3 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 271/527 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58170451; called by muse, mutect2, varscan2
- TLK1 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 76/126 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV62631291; called by muse, mutect2
- TMEM108 | c.860del p.G287Vfs*124 | Frame Shift Del (DEL) | VAF 49/148 reads (33%) | catalogued as rs1370425012, COSV100419643; called by mutect2, pindel, varscan2
- TMEM176B | c.692A>C p.N231T | Missense Mutation (SNP) | VAF 79/107 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs756282550; called by muse, varscan2
- TMEM229A | c.611C>A p.A204E | Missense Mutation (SNP) | VAF 214/266 reads (80%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as COSV71900235; called by muse, varscan2
- TNIK | c.2705C>G p.T902S | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs770114109; called by muse, mutect2, varscan2
- TNR | c.3330G>T p.Q1110H | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV54895421; called by muse, mutect2, varscan2
- TRBC2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 76/107 reads (71%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.171); catalogued as rs544245790; called by muse, mutect2, varscan2
- TRIM69 | c.85A>G p.K29E | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs1432108521; called by muse, mutect2, varscan2
- TRIP11 | c.5411G>T p.R1804L | Missense Mutation (SNP) | VAF 166/428 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50920202; called by muse, varscan2
- TRPA1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 133/534 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV51558957; called by muse, mutect2, varscan2
- TTC27 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1335498755; called by muse, mutect2, varscan2
- TUBGCP2 | c.1024+1G>T p.X342_splice | Splice Site (SNP) | VAF 69/152 reads (45%) | catalogued as rs752909493; called by muse, mutect2, varscan2
- UGT3A1 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 150/301 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV57096751; called by muse, mutect2, varscan2
- USH1G | c.992G>T p.R331L | Missense Mutation (SNP) | VAF 102/247 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as rs879066143, COSV58883959; called by muse, mutect2, varscan2
- USH2A | c.1529A>G p.D510G | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV100236511; called by muse, mutect2, varscan2
- VRTN | c.1326G>T p.K442N | Missense Mutation (SNP) | VAF 98/224 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV56439984; called by muse, mutect2, varscan2
- VWA2 | c.805G>T p.V269L | Missense Mutation (SNP) | VAF 85/203 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV53912237; called by muse, mutect2, varscan2
- XIRP2 | c.4255G>A p.E1419K (on ENST00000628543; = p.E1594K on NM_152381.6) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV54698726; called by muse, varscan2
- XPOT | c.2615A>T p.H872L | Missense Mutation (SNP) | VAF 77/201 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV60348656; called by muse, mutect2, varscan2
- ZBP1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 92/197 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs201431325; called by muse, mutect2, varscan2
- ZFHX4 | c.5644G>T p.G1882C | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as rs1259514965; called by muse, mutect2, varscan2
- ZGRF1 | c.3074C>T p.T1025M | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs765127544; called by muse, mutect2, varscan2
- ZNF180 | c.1598G>A p.S533N | Missense Mutation (SNP) | VAF 102/252 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV55419791; called by muse, mutect2, varscan2
- ZNF28 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 134/400 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.286); catalogued as rs139191052; called by muse, mutect2, varscan2
- ZNF658 | c.2380G>A p.G794R | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1333638999; called by mutect2, varscan2
- ZNF735 | c.165G>C p.L55= | Splice Region (SNP) | VAF 35/98 reads (36%) | catalogued as rs749282296; called by muse, mutect2
- ZPLD1 | c.1151C>G p.T384R (on ENST00000466937 / NM_001329788.1; = p.T400R on NM_175056.2) | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs201532080; called by muse, mutect2, varscan2
- AATF | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 115/428 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ABCB5 | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- ABCB5 | c.2348G>T p.W783L (on ENST00000404938 / NM_001163941.2; = p.W338L on NM_178559.6) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ABCG2 | c.501G>C p.E167D | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- AC006059.2 | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC107871.1 | c.83G>T p.R28I | Missense Mutation (SNP) | VAF 374/668 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ACADM | c.1060G>C p.A354P | Missense Mutation (SNP) | VAF 146/382 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACCS | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- ADAM19 | c.601-1G>T p.X201_splice | Splice Site (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
- ADAM8 | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS19 | c.1620-1G>A p.X540_splice | Splice Site (SNP) | VAF 59/243 reads (24%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.2859C>A p.S953R | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADAMTS2 | c.775A>G p.R259G | Missense Mutation (SNP) | VAF 146/645 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAMTS6 | c.1727G>T p.G576V | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADCY1 | c.1563G>C p.E521D | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADCY4 | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ADCY5 | c.181G>T p.V61L | Missense Mutation (SNP) | VAF 119/244 reads (49%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ADGRL4 | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- ADGRV1 | c.3504G>T p.E1168D | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.938); called by muse, mutect2
- AGXT | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 104/384 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AHNAK2 | c.2114T>A p.V705E | Missense Mutation (SNP) | VAF 191/519 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- AK5 | c.1094C>A p.T365N (on ENST00000354567 / NM_174858.3; = p.T339N on NM_012093.4) | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKR1B10 | c.564C>A p.H188Q | Missense Mutation (SNP) | VAF 86/107 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AL592490.1 | c.2005G>T p.G669* | Nonsense Mutation (SNP) | VAF 36/124 reads (29%) | called by muse, mutect2, varscan2
- ALK | c.1535A>T p.Q512L | Missense Mutation (SNP) | VAF 87/326 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMER1 | c.1339G>A p.G447S | Missense Mutation (SNP) | VAF 51/59 reads (86%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AMER3 | c.2441G>T p.G814V | Missense Mutation (SNP) | VAF 101/414 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- AMPD3 | c.1472A>T p.K491M (on ENST00000396553 / NM_001025389.2; = p.K500M on NM_000480.3) | Missense Mutation (SNP) | VAF 153/397 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- AMPH | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 165/388 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- ANGPT1 | c.717A>T p.R239S | Missense Mutation (SNP) | VAF 42/377 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.3365A>G p.N1122S | Missense Mutation (SNP) | VAF 123/278 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK2 | c.10689G>T p.Q3563H | Missense Mutation (SNP) | VAF 88/342 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, varscan2
- ANKRD27 | c.1193C>A p.T398N | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- ANKRD52 | c.1991A>T p.H664L | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, varscan2
- ANO4 | c.1617G>A p.W539* (on ENST00000392977 / NM_001286615.2; = p.W504* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 62/174 reads (36%) | called by muse, mutect2, varscan2
- ANOS1 | c.1998G>T p.K666N | Missense Mutation (SNP) | VAF 64/75 reads (85%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ANTXR1 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 99/204 reads (49%) | called by muse, mutect2, varscan2
- AP3B1 | c.2090G>T p.G697V | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- ARAP2 | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 73/146 reads (50%) | called by muse, mutect2, varscan2
- ARHGAP17 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ARHGEF17 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 69/470 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ARID5A | c.1411G>C p.A471P | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2
- ARL6IP1 | c.245A>T p.Y82F | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- ASAH2 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 135/301 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASAP2 | c.2756C>T p.A919V | Missense Mutation (SNP) | VAF 131/249 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASTN1 | c.3538C>A p.L1180I | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATAD3C | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 145/303 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ATF7IP | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 45/53 reads (85%) | called by muse, mutect2, varscan2
- ATPAF2 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- AVL9 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- B3GALT1 | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- B4GALNT4 | c.1097T>C p.V366A | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BCL3 | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- BCL9 | c.4117_4123del p.G1373Wfs*6 | Frame Shift Del (DEL) | VAF 45/129 reads (35%) | called by mutect2, pindel, varscan2
- BICRA | c.4550G>T p.R1517L | Missense Mutation (SNP) | VAF 195/514 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BIRC3 | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BNIP1 | c.550A>T p.I184F | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- BNIP5 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 293/541 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- BRCC3 | c.342del p.M115* | Frame Shift Del (DEL) | VAF 102/161 reads (63%) | called by mutect2, pindel, varscan2
- BRSK1 | c.1489G>C p.A497P | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTNL3 | c.1327C>A p.P443T | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BUB1 | c.2177G>A p.S726N | Missense Mutation (SNP) | VAF 128/200 reads (64%) | SIFT tolerated (0.35); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- C20orf194 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- C2CD3 | c.4865G>T p.R1622L | Missense Mutation (SNP) | VAF 107/235 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- C4orf50 | c.490A>T p.S164C (on ENST00000324058; = p.S1396C on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- C8A | c.247A>G p.S83G | Missense Mutation (SNP) | VAF 117/298 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- C8A | c.1066G>T p.V356L | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- C9orf131 | c.1685T>A p.L562H | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CACNA1D | c.6241G>C p.V2081L (on ENST00000350061 / NM_001128840.3; = p.V2101L on NM_000720.4) | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CACNA1E | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 177/479 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CALCRL | c.124A>T p.M42L | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMSAP1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- CAPN14 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPN9 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPRIN1 | c.1122+1G>T p.X374_splice | Splice Site (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- CASD1 | c.1433A>G p.Y478C | Missense Mutation (SNP) | VAF 100/125 reads (80%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CCDC151 | c.1535C>A p.A512E | Missense Mutation (SNP) | VAF 75/106 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC168 | c.12196A>G p.I4066V | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CCDC171 | c.2890C>T p.P964S | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.509); called by muse, mutect2
- CCDC182 | c.67A>T p.I23L | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC185 | c.35A>T p.Y12F | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- CCDC61 | c.1094A>T p.Q365L | Missense Mutation (SNP) | VAF 144/369 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CCDC62 | c.1424G>T p.S475I | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, varscan2
- CCDC82 | c.1205A>G p.Y402C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC87 | c.1978G>T p.E660* | Nonsense Mutation (SNP) | VAF 106/291 reads (36%) | called by muse, mutect2, varscan2
- CCL19 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCN3 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 24/233 reads (10%) | called by muse, mutect2
- CCT6A | c.1583C>G p.S528C | Missense Mutation (SNP) | VAF 119/300 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CD3D | c.401C>A p.S134Y | Missense Mutation (SNP) | VAF 226/492 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by mutect2, varscan2
- CDC45 | c.1091A>G p.H364R | Missense Mutation (SNP) | VAF 194/217 reads (89%) | SIFT tolerated (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CDH13 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH23 | c.1155G>C p.M385I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH6 | c.1599T>A p.S533R | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- CDHR1 | c.348+1G>C p.X116_splice | Splice Site (SNP) | VAF 120/277 reads (43%) | called by muse, mutect2, varscan2
- CEACAM20 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CELP | n.2347C>A | Splice Region (SNP) | VAF 111/496 reads (22%) | called by muse, mutect2, varscan2
- CELSR3 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CEMP1 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 120/279 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CEP135 | c.2092C>T p.Q698* | Nonsense Mutation (SNP) | VAF 84/162 reads (52%) | called by muse, mutect2, varscan2
- CEP295NL | c.569G>T p.R190M | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CFAP47 | c.2253dup p.G752Wfs*6 | Frame Shift Ins (INS) | VAF 48/81 reads (59%) | called by mutect2, pindel, varscan2
- CFAP54 | c.7964A>T p.Y2655F | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHORDC1 | c.64+5G>T | Splice Region (SNP) | VAF 261/627 reads (42%) | called by muse, mutect2, varscan2
- CHST10 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHSY3 | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 73/132 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CILP2 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 190/689 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLDN17 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- CLHC1 | c.773A>T p.Q258L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLIP2 | c.1852G>T p.D618Y | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CLN8 | c.450G>T p.L150F | Missense Mutation (SNP) | VAF 116/150 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CMYA5 | c.1272G>C p.K424N | Missense Mutation (SNP) | VAF 71/131 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- CNBD1 | c.894T>A p.Y298* | Nonsense Mutation (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
- CNTFR | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 176/575 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN3 | c.1685T>A p.L562* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | called by muse, mutect2, varscan2
- COL11A2 | c.3820G>C p.D1274H (on ENST00000341947 / NM_080680.3; = p.D1167H on NM_080679.2) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COL14A1 | c.2731C>A p.L911M | Missense Mutation (SNP) | VAF 106/221 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL15A1 | c.4089C>G p.D1363E | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- COL24A1 | c.2797G>T p.G933C | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.2971A>G p.M991V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- COPA | c.1329G>C p.E443D | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- COQ2 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- CORO2A | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CPAMD8 | c.2266G>T p.G756C (on ENST00000651564; = p.G709C on NM_015692.5) | Missense Mutation (SNP) | VAF 51/62 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CPT1A | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 149/378 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CRB1 | c.2456C>T p.A819V | Missense Mutation (SNP) | VAF 99/281 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CSDE1 | c.1246G>T p.G416C (on ENST00000358528 / NM_001007553.3; = p.G385C on NM_007158.6) | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CSMD3 | c.9575G>T p.G3192V (on ENST00000297405 / NM_001363185.1; = p.G3023V on NM_052900.3) | Missense Mutation (SNP) | VAF 135/310 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CSMD3 | c.4582T>A p.C1528S (on ENST00000297405 / NM_001363185.1; = p.C1424S on NM_052900.3) | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSN2 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CTNNA3 | c.257A>T p.E86V | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- CUX2 | c.1526C>A p.P509Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CUX2 | c.2358C>A p.D786E | Missense Mutation (SNP) | VAF 238/554 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, varscan2
- CYLC2 | c.886G>C p.A296P | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CYP4B1 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP7A1 | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYTH3 | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DAG1 | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.644); called by muse, varscan2
- DBX2 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 255/684 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DCAF13 | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, varscan2
- DCAF17 | c.222dup p.V75Cfs*7 | Frame Shift Ins (INS) | VAF 181/421 reads (43%) | called by mutect2, pindel, varscan2
- DCD | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 74/176 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- DDC | c.1361C>A p.T454K | Missense Mutation (SNP) | VAF 152/350 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by mutect2, varscan2
- DDC | c.494A>T p.H165L | Missense Mutation (SNP) | VAF 163/395 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DENND4C | c.3776A>T p.E1259V (on ENST00000434457 / NM_001330640.2; = p.E1210V on NM_017925.7) | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DEPDC1 | c.1064A>T p.N355I | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DGKI | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- DGKK | c.1763G>A p.W588* | Nonsense Mutation (SNP) | VAF 134/156 reads (86%) | called by muse, varscan2
- DHX34 | c.3380_3402del p.D1127Gfs*43 | Frame Shift Del (DEL) | VAF 68/230 reads (30%) | called by mutect2, pindel
- DHX37 | c.74_75insG p.E26Rfs*19 | Frame Shift Ins (INS) | VAF 9/32 reads (28%) | called by mutect2, varscan2
- DHX9 | c.857T>C p.L286P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DIDO1 | c.2159G>C p.R720P | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DLGAP4 | c.1119G>T p.M373I | Missense Mutation (SNP) | VAF 177/392 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DMRT1 | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DMRT3 | c.1187C>G p.T396R | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- DNAH1 | c.12634G>C p.D4212H | Missense Mutation (SNP) | VAF 90/192 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH11 | c.12899dup p.I4301Yfs*4 | Frame Shift Ins (INS) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- DOC2B | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 109/155 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DOCK2 | c.2395A>T p.I799F | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DOCK2 | c.3117G>T p.Q1039H | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DOCK2 | c.3118G>T p.D1040Y | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- DOCK5 | c.4097G>T p.G1366V | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DPP10 | c.943A>T p.K315* | Nonsense Mutation (SNP) | VAF 40/200 reads (20%) | called by muse, varscan2
- DQX1 | c.1967T>A p.L656H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- DRC1 | c.1842dup p.P615Tfs*10 | Frame Shift Ins (INS) | VAF 71/180 reads (39%) | called by pindel, varscan2
- DTWD1 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 119/209 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DUSP10 | c.394G>T p.G132W | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- DVL1 | c.1111A>G p.T371A | Missense Mutation (SNP) | VAF 256/562 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- DVL3 | c.1331-1G>A p.X444_splice | Splice Site (SNP) | VAF 111/284 reads (39%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.4846G>T p.G1616* | Nonsense Mutation (SNP) | VAF 77/204 reads (38%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.13924G>T p.V4642F | Missense Mutation (SNP) | VAF 176/480 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, varscan2
- DYNC2H1 | c.12332T>C p.V4111A | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, varscan2
- DYRK1B | c.1169G>C p.R390P | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- E4F1 | c.1544A>T p.D515V | Missense Mutation (SNP) | VAF 302/719 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EFS | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EIF2B2 | c.329A>G p.H110R | Missense Mutation (SNP) | VAF 252/669 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, varscan2
- EIF4A3 | c.155G>C p.G52A | Missense Mutation (SNP) | VAF 216/500 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELAVL2 | c.145A>T p.N49Y | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- EML5 | c.1505G>T p.C502F | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- EMSY | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENOSF1 | c.748G>T p.D250Y (on ENST00000340116 / NM_001354066.2; = p.D202Y on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- EOMES | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 298/696 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EPB41L4A | c.1487G>C p.R496P | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- EPG5 | c.6225+1G>T p.X2075_splice | Splice Site (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- EPHA5 | c.845G>T p.W282L | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPN1 | c.966G>T p.R322S (on ENST00000270460 / NM_001321263.1; = p.R297S on NM_013333.3) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.66); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ERBB4 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 536/915 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ERCC6 | c.2940G>C p.Q980H | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ESS2 | c.657G>T p.K219N | Missense Mutation (SNP) | VAF 254/301 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ETS2 | c.312G>A p.W104* | Nonsense Mutation (SNP) | VAF 45/82 reads (55%) | called by muse, mutect2, varscan2
- ETV7 | c.808-2A>G p.X270_splice | Splice Site (SNP) | VAF 28/127 reads (22%) | called by muse, mutect2, varscan2
- EXD2 | c.449G>T p.R150I (on ENST00000312994 / NM_001193362.1; = p.R25I on NM_018199.3) | Missense Mutation (SNP) | VAF 104/286 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- F13A1 | c.302G>T p.R101M | Missense Mutation (SNP) | VAF 312/799 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- F8 | c.6218A>G p.H2073R | Missense Mutation (SNP) | VAF 89/105 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- FAM102A | c.934G>A p.V312M (on ENST00000373095 / NM_001035254.3; = p.V170M on NM_203305.2) | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FAM126A | c.1468A>G p.K490E | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FAM135B | c.2403G>T p.M801I | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM163A | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM178B | c.1151G>T p.S384I | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- FAM47B | c.1929A>T p.K643N | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.288); called by muse, varscan2
- FAM47E | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- FAM98C | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FANCM | c.2002+5A>T | Splice Region (SNP) | VAF 75/210 reads (36%) | called by muse, mutect2, varscan2
- FAT3 | c.65T>A p.L22H | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- FBH1 | c.2323G>T p.G775W (on ENST00000362091 / NM_178150.3; = p.G826W on NM_032807.4) | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBRSL1 | c.1343A>C p.H448P | Missense Mutation (SNP) | VAF 240/675 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- FBXO10 | c.1235A>T p.Q412L | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- FBXO11 | c.1477G>T p.V493F (on ENST00000403359 / NM_001190274.2; = p.V409F on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); called by muse, varscan2
- FBXO46 | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FCHSD2 | c.877T>C p.F293L | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FHOD3 | c.1235G>C p.R412T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FKRP | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- FLCN | c.1174C>A p.R392= | Splice Region (SNP) | VAF 280/351 reads (80%) | called by muse, mutect2, varscan2
- FLNC | c.5918A>G p.D1973G | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FN1 | c.3423del p.G1142Afs*2 | Frame Shift Del (DEL) | VAF 45/184 reads (24%) | called by pindel, varscan2
- FNDC7 | c.2201G>C p.*734Sext*11 | Nonstop Mutation (SNP) | VAF 63/213 reads (30%) | called by muse, mutect2, varscan2
- FNTA | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FOCAD | c.536G>C p.W179S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- FOXD2 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 26/759 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- FOXF2 | c.802C>A p.H268N | Missense Mutation (SNP) | VAF 76/271 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.009); called by mutect2, varscan2
- FOXN3 | c.991C>G p.P331A (on ENST00000261302; = p.P309A on NM_005197.4) | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, varscan2
- FPR2 | c.664G>C p.G222R | Missense Mutation (SNP) | VAF 100/324 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FREM3 | c.337C>A p.R113S | Missense Mutation (SNP) | VAF 93/174 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FSCB | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- FSTL4 | c.962G>A p.C321Y | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FTL | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 210/396 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- FUS | c.917del p.K306Sfs*16 | Frame Shift Del (DEL) | VAF 175/526 reads (33%) | called by mutect2, pindel, varscan2
- FUT9 | c.755A>T p.Y252F | Missense Mutation (SNP) | VAF 98/116 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FYB2 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.762); called by muse, varscan2
- GABBR1 | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 131/282 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRA1 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GAL3ST3 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 151/364 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GJA4 | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 165/337 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- GLB1L2 | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- GLT8D1 | c.94T>G p.L32V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GMIP | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GNA11 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 106/137 reads (77%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- GNAI3 | c.373G>T p.G125* | Nonsense Mutation (SNP) | VAF 26/107 reads (24%) | called by muse, varscan2
- GOLGA2 | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- GOLGA6L22 | c.436A>G p.I146V | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- GPATCH1 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- GPR158 | c.359C>G p.P120R | Missense Mutation (SNP) | VAF 97/286 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPSM1 | c.1372G>T p.G458C | Missense Mutation (SNP) | VAF 75/305 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- GRIA3 | c.2569A>G p.M857V | Missense Mutation (SNP) | VAF 137/178 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, varscan2
- GRID2 | c.1314G>T p.M438I | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- GRM7 | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 117/242 reads (48%) | called by muse, mutect2, varscan2
- HAS2 | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECTD1 | c.6965A>G p.D2322G | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HELZ2 | c.3029G>T p.R1010L (on ENST00000467148 / NM_001037335.2; = p.R441L on NM_033405.3) | Missense Mutation (SNP) | VAF 177/580 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPH | c.2992G>T p.D998Y (on ENST00000343002; = p.D731Y on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLA-DOB | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 120/200 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- HNRNPA2B1 | c.1037dup p.Y347Lfs*20 (on ENST00000354667 / NM_031243.3; = p.Y335Lfs*20 on NM_002137.4) | Frame Shift Ins (INS) | VAF 120/346 reads (35%) | called by mutect2, pindel, varscan2
- IFNA6 | c.135G>T p.R45S | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- IFNA6 | c.134G>T p.R45M | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- IGKV3-15 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV7-46 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 115/128 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IL1RL2 | c.350G>C p.W117S | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IQCK | c.221A>C p.K74T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- IRF4 | c.1352A>T p.E451V | Missense Mutation (SNP) | VAF 170/488 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ITFG2 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 63/92 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA5 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA8 | c.2976C>G p.S992R | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA8 | c.1517C>A p.T506N | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- ITGB3BP | c.227A>G p.K76R | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.68); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- ITGBL1 | c.1411T>A p.C471S | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- ITIH2 | c.1688A>G p.D563G | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JPH4 | c.518C>A p.P173Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- JPH4 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KALRN | c.3065T>C p.L1022S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNA7 | c.1106T>C p.V369A | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KCNAB2 | c.779C>A p.P260Q | Missense Mutation (SNP) | VAF 133/470 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- KCNB1 | c.711C>G p.I237M | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNG1 | c.775-3del | Splice Region (DEL) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- KCNMA1 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 146/287 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KCNT1 | c.1394A>T p.N465I (on ENST00000488444; = p.N484I on NM_020822.3) | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by mutect2, varscan2
- KCNT1 | c.2420G>T p.R807I (on ENST00000488444; = p.R826I on NM_020822.3) | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- KDM4C | c.436-1G>T p.X146_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- KIAA0232 | c.1558G>T p.D520Y | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0319L | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KIAA0753 | c.1157G>A p.C386Y | Missense Mutation (SNP) | VAF 82/103 reads (80%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- KIF19 | c.2243del p.G748Afs*28 | Frame Shift Del (DEL) | VAF 136/448 reads (30%) | called by mutect2, pindel, varscan2
- KIF26B | c.2500C>A p.H834N | Missense Mutation (SNP) | VAF 128/296 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KIF4B | c.810G>T p.L270F | Missense Mutation (SNP) | VAF 81/424 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIR3DL2 | c.752A>C p.D251A | Missense Mutation (SNP) | VAF 135/271 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- KRT39 | c.688del p.L230Sfs*24 | Frame Shift Del (DEL) | VAF 21/62 reads (34%) | called by mutect2, pindel, varscan2
- KRT72 | c.1286A>T p.K429M | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KRT77 | c.1394C>T p.T465I | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- LAMC3 | c.3593G>T p.R1198M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- LENG1 | c.748dup p.Q250Pfs*32 | Frame Shift Ins (INS) | VAF 96/457 reads (21%) | called by mutect2, pindel, varscan2
- LPA | c.1055T>A p.L352Q | Missense Mutation (SNP) | VAF 69/882 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LRIT3 | c.1143C>A p.S381R | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1 | c.12867G>T p.Q4289H | Missense Mutation (SNP) | VAF 112/307 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRP2 | c.70A>C p.S24R | Missense Mutation (SNP) | VAF 169/360 reads (47%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); called by mutect2, varscan2
- LRRC15 | c.981T>A p.N327K | Missense Mutation (SNP) | VAF 27/422 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- LRRTM1 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 75/132 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- LTBP1 | c.4271-2A>C p.X1424_splice (on ENST00000404816 / NM_206943.4; = p.X1098_splice on NM_000627.4) | Splice Site (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- M1AP | c.746T>A p.I249N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MAN2A1 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 290/498 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- MAP2 | c.1374dup p.E459Rfs*3 | Frame Shift Ins (INS) | VAF 34/75 reads (45%) | called by mutect2, pindel, varscan2
- MAPK4 | c.1250A>C p.E417A | Missense Mutation (SNP) | VAF 78/254 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MASP2 | c.691T>A p.F231I | Missense Mutation (SNP) | VAF 98/207 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCTP1 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- MDM4 | c.716G>T p.W239L | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, varscan2
- MEF2C | c.986A>G p.D329G | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, varscan2
- MGAM2 | c.5213A>T p.H1738L | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.697); called by muse, varscan2
- MGAT4B | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 91/284 reads (32%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MIA2 | c.770C>G p.A257G | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, varscan2
- MMP13 | c.512-2A>G p.X171_splice | Splice Site (SNP) | VAF 123/292 reads (42%) | called by muse, mutect2, varscan2
- MRAP2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 89/109 reads (82%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MROH2B | c.919+1del p.X307_splice | Splice Site (DEL) | VAF 25/77 reads (32%) | called by mutect2, pindel, varscan2
- MROH2B | c.591G>T p.W197C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MROH7 | c.1819G>C p.A607P | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- MRTFB | c.245A>C p.H82P | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSH5 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- MUC16 | c.9550C>A p.P3184T | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC2 | c.3483G>T p.E1161D | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- MUC22 | c.2380G>T p.E794* | Nonsense Mutation (SNP) | VAF 111/198 reads (56%) | called by muse, mutect2, varscan2
- MUC4 | c.14008del p.H4670Tfs*102 (on ENST00000463781 / NM_018406.7; = p.H434Tfs*102 on NM_004532.6) | Frame Shift Del (DEL) | VAF 104/261 reads (40%) | called by mutect2, pindel, varscan2
- MUC5AC | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT tolerated (0.21); called by muse, varscan2
- MUC5AC | c.16578C>A p.Y5526* | Nonsense Mutation (SNP) | VAF 143/331 reads (43%) | called by muse, mutect2, varscan2
- MYF5 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 201/405 reads (50%) | called by muse, mutect2, varscan2
- MYLK | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- MYO1D | c.2193C>A p.Y731* | Nonsense Mutation (SNP) | VAF 143/407 reads (35%) | called by muse, mutect2, varscan2
- MYO5B | c.5476C>T p.P1826S | Missense Mutation (SNP) | VAF 128/302 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MYO5B | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 132/283 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- MYT1 | c.1792C>G p.R598G | Missense Mutation (SNP) | VAF 73/222 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NAT10 | c.2653G>T p.E885* | Nonsense Mutation (SNP) | VAF 92/241 reads (38%) | called by muse, mutect2, varscan2
- NAV2 | c.1888G>T p.G630C (on ENST00000396087 / NM_001244963.2; = p.G607C on NM_145117.5) | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, varscan2
- NAV2 | c.1918G>C p.A640P (on ENST00000396087 / NM_001244963.2; = p.A617P on NM_145117.5) | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- NAV3 | c.424G>T p.V142F | Missense Mutation (SNP) | VAF 104/240 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- NBEA | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 63/82 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NEB | c.19081C>A p.R6361S | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- NEB | c.5646G>C p.K1882N | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NEB | c.4304T>A p.V1435E | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NEBL | c.2572G>T p.E858* | Nonsense Mutation (SNP) | VAF 119/268 reads (44%) | called by muse, mutect2, varscan2
- NELL2 | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- NEU1 | c.1067G>T p.W356L | Missense Mutation (SNP) | VAF 366/614 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFRKB | c.2417G>T p.R806L (on ENST00000446488 / NM_001143835.2; = p.R831L on NM_006165.3) | Missense Mutation (SNP) | VAF 152/425 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NIPAL4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKAIN1 | c.192+1G>T p.X64_splice | Splice Site (SNP) | VAF 55/99 reads (56%) | called by muse, mutect2, varscan2
- NLRP5 | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 103/212 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NOBOX | c.1855C>A p.P619T | Missense Mutation (SNP) | VAF 55/77 reads (71%) | SIFT tolerated (0.31); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- NOTCH4 | c.3497C>A p.P1166Q | Missense Mutation (SNP) | VAF 142/254 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOX5 | c.1347G>A p.M449I | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPTX1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 290/706 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- NRIP1 | c.1208G>C p.S403T | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- NRXN3 | c.2046G>T p.E682D (on ENST00000335750 / NM_001330195.2; = p.E309D on NM_004796.6) | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NSUN6 | c.1260G>T p.Q420H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- NT5C1B | c.1252T>A p.Y418N (on ENST00000359846 / NM_001199086.2; = p.Y358N on NM_033253.4) | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NTNG1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, varscan2
- NTRK1 | c.689C>A p.T230K | Missense Mutation (SNP) | VAF 181/390 reads (46%) | SIFT tolerated (0.83); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NTS | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- OASL | c.512dup p.E172* | Frame Shift Ins (INS) | VAF 35/107 reads (33%) | called by mutect2, pindel, varscan2
- OR10G7 | c.115G>T p.G39W | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10W1 | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- OR13A1 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- OR1G1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 73/95 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- OR2A25 | c.140T>A p.L47H | Missense Mutation (SNP) | VAF 114/168 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2F1 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 56/80 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- OR4K1 | c.562G>C p.A188P | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR52E4 | c.550A>T p.R184W | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- OR5B12 | c.731C>A p.T244N | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- OR5B2 | c.364G>C p.A122P | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- OR5B3 | c.97T>A p.Y33N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5H14 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- OR5M3 | c.698A>G p.Q233R | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6N1 | c.320T>A p.L107H | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR8U1 | c.698_699insT p.R234Kfs*30 | Frame Shift Ins (INS) | VAF 46/136 reads (34%) | called by pindel, varscan2
- OR9A4 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OSM | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.15); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PAG1 | c.143A>T p.Q48L | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAPOLB | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PAX9 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 154/371 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH17 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 344/924 reads (37%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.1292G>T p.R431L | Missense Mutation (SNP) | VAF 100/171 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- PCDHB10 | c.2228G>C p.G743A | Missense Mutation (SNP) | VAF 306/368 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by mutect2, varscan2
- PCDHB12 | c.510C>G p.Y170* | Nonsense Mutation (SNP) | VAF 65/137 reads (47%) | called by muse, mutect2, varscan2
- PCDHB5 | c.2030C>A p.P677Q | Missense Mutation (SNP) | VAF 339/580 reads (58%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, varscan2
- PCDHGA5 | c.557C>A p.T186N | Missense Mutation (SNP) | VAF 290/346 reads (84%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PCDHGA7 | c.69del p.W24Gfs*54 | Frame Shift Del (DEL) | VAF 40/81 reads (49%) | called by mutect2, pindel, varscan2
- PCMTD1 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCNX3 | c.4954-1G>T p.X1652_splice | Splice Site (SNP) | VAF 67/155 reads (43%) | called by muse, mutect2, varscan2
- PCOLCE2 | c.786_787insC p.G263Rfs*40 | Frame Shift Ins (INS) | VAF 30/81 reads (37%) | called by mutect2, pindel, varscan2
- PDCD6IP | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PDE1C | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 95/271 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PHLDB2 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGN | c.1600G>T p.V534L | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKDCC | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- PKHD1 | c.10279T>A p.L3427I | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.212); called by muse, mutect2
- PKHD1 | c.4630G>T p.A1544S | Missense Mutation (SNP) | VAF 283/483 reads (59%) | SIFT tolerated (0.82); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PLCH2 | c.2260G>T p.G754W | Missense Mutation (SNP) | VAF 152/437 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLGRKT | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLXNA4 | c.2264_2272del p.F755_S757del | In Frame Del (DEL) | VAF 44/68 reads (65%) | called by pindel, varscan2
- PLXNC1 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 44/122 reads (36%) | called by muse, mutect2, varscan2
- PNLIPRP2 | c.1192G>T p.D398Y (on ENST00000611850; = p.D399Y on NM_005396.5) | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- POLG | c.685G>T p.V229L | Missense Mutation (SNP) | VAF 98/352 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POLM | c.642G>C p.Q214H | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- POTEG | c.335G>C p.S112T | Missense Mutation (SNP) | VAF 239/1131 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POU2F3 | c.978G>T p.R326S | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPARGC1A | c.1868G>T p.R623L | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPP1R10 | c.313G>T p.V105L | Missense Mutation (SNP) | VAF 92/164 reads (56%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP4R3A | c.1618G>T p.V540L (on ENST00000554943 / NM_001366432.1; = p.V527L on NM_001284280.1) | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, varscan2
- PRAMEF4 | c.1386C>G p.D462E | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by mutect2, varscan2
- PRDM15 | c.2730G>C p.M910I | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PROS1 | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PRPF4B | c.1909G>T p.D637Y | Missense Mutation (SNP) | VAF 43/346 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- PRR35 | c.1562C>A p.A521D | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRUNE2 | c.6464C>A p.P2155Q | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- PRUNE2 | c.6098C>A p.S2033Y | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PSG6 | c.937del p.D313Tfs*13 | Frame Shift Del (DEL) | VAF 77/250 reads (31%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1609-1G>A p.X537_splice | Splice Site (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- PTPRC | c.2168T>A p.I723N | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRH | c.1869C>G p.S623R | Missense Mutation (SNP) | VAF 128/448 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPRZ1 | c.5237del p.N1746Tfs*12 | Frame Shift Del (DEL) | VAF 78/143 reads (55%) | called by mutect2, pindel, varscan2
- PXDN | c.3859G>A p.D1287N | Missense Mutation (SNP) | VAF 123/242 reads (51%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- R3HDM2 | c.1793A>G p.Q598R | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- RALGDS | c.2680G>T p.G894* | Nonsense Mutation (SNP) | VAF 77/230 reads (33%) | called by muse, mutect2, varscan2
- RASGRP3 | c.1434C>A p.F478L (on ENST00000402538 / NM_001349975.2; = p.F477L on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- RBM10 | c.2203del p.E735Rfs*67 | Frame Shift Del (DEL) | VAF 228/327 reads (70%) | called by mutect2, pindel, varscan2
- RELN | c.3755T>G p.M1252R | Missense Mutation (SNP) | VAF 164/226 reads (73%) | SIFT tolerated (0.53); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RNF150 | c.171_172insA p.G58Rfs*74 | Frame Shift Ins (INS) | VAF 85/355 reads (24%) | called by mutect2, pindel, varscan2
- ROBO2 | c.3376G>A p.D1126N | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ROBO4 | c.1709C>A p.P570H | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPAP2 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 108/207 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- RPL38 | c.4-2A>T p.X2_splice | Splice Site (SNP) | VAF 270/647 reads (42%) | called by muse, mutect2, varscan2
- RPS6KA1 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- RPS6KC1 | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 134/315 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, varscan2
- RPS6KC1 | c.472+1G>T p.X158_splice | Splice Site (SNP) | VAF 29/76 reads (38%) | called by muse, varscan2
- RRBP1 | c.2992G>T p.G998C (on ENST00000377813 / NM_001365613.2; = p.G565C on NM_004587.3) | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTF1 | c.2083A>G p.R695G | Missense Mutation (SNP) | VAF 71/96 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- RYR1 | c.2045G>T p.R682L | Missense Mutation (SNP) | VAF 167/385 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR1 | c.9854G>A p.W3285* | Nonsense Mutation (SNP) | VAF 22/718 reads (3%) | called by muse, mutect2
- RYR3 | c.2220C>A p.D740E | Missense Mutation (SNP) | VAF 89/113 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- S100B | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- SAFB | c.1407G>T p.K469N | Missense Mutation (SNP) | VAF 59/76 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- SALL3 | c.983C>A p.A328E | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SBF1 | c.16del p.D6Tfs*78 | Frame Shift Del (DEL) | VAF 74/451 reads (16%) | called by mutect2, pindel, varscan2
- SCN9A | c.2166G>T p.L722F (on ENST00000303354; = p.L711F on NM_002977.3) | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- SERPINB7 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SERPINB7 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- SH2D3C | c.908G>T p.S303I (on ENST00000314830 / NM_170600.3; = p.S146I on NM_005489.4) | Missense Mutation (SNP) | VAF 246/453 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SH3D21 | c.1116del p.S373Afs*20 (on ENST00000453908 / NM_001162530.2; = p.S262Afs*20 on NM_024676.5) | Frame Shift Del (DEL) | VAF 25/55 reads (45%) | called by mutect2, varscan2
- SHANK3 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 257/294 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SHISA6 | c.1317C>A p.Y439* (on ENST00000409168 / NM_001173461.1; = p.Y490* on NM_207386.4) | Nonsense Mutation (SNP) | VAF 289/368 reads (79%) | called by muse, mutect2, varscan2
- SHTN1 | c.1405G>T p.D469Y | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SIGLEC1 | c.1732del p.R578Gfs*86 | Frame Shift Del (DEL) | VAF 171/562 reads (30%) | called by mutect2, pindel, varscan2
- SKAP1 | c.501C>A p.H167Q | Missense Mutation (SNP) | VAF 116/220 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- SKOR1 | c.2398G>T p.E800* | Nonsense Mutation (SNP) | VAF 142/511 reads (28%) | called by mutect2, varscan2
- SLAIN2 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC22A2 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 113/146 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SLC22A6 | c.177G>C p.K59N | Missense Mutation (SNP) | VAF 206/480 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- SLC22A6 | c.175A>C p.K59Q | Missense Mutation (SNP) | VAF 210/480 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- SLC23A2 | c.208A>T p.S70C | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC27A2 | c.629G>T p.W210L | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC27A6 | c.1732G>T p.V578L | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- SLC34A1 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 371/460 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SLC45A4 | c.1070C>T p.P357L (on ENST00000517878 / NM_001286646.2; = p.P306L on NM_001080431.2) | Missense Mutation (SNP) | VAF 221/666 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SLC5A8 | c.1527-1G>T p.X509_splice | Splice Site (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- SLC6A4 | c.1018G>T p.G340C | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC9A1 | c.1770G>T p.E590D | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLC9A2 | c.537G>T p.W179C | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLITRK3 | c.1858G>T p.A620S | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNRNP200 | c.2957G>T p.R986L | Missense Mutation (SNP) | VAF 84/320 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SNTG2 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SOCS6 | c.854T>C p.V285A | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.138); called by muse, varscan2
- SOGA1 | c.4699G>T p.G1567C | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SOX6 | c.1224A>T p.R408S (on ENST00000528429 / NM_001145819.2; = p.R367S on NM_017508.3) | Missense Mutation (SNP) | VAF 122/314 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SP1 | c.1540G>T p.G514C (on ENST00000327443 / NM_138473.3; = p.G507C on NM_003109.1) | Missense Mutation (SNP) | VAF 117/284 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, varscan2
- SP100 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | called by muse, varscan2
- SP110 | c.1437A>T p.K479N | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA3 | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SPIC | c.226T>A p.F76I | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SPIRE1 | c.923T>C p.M308T | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- SPSB3 | c.970C>A p.R324S | Missense Mutation (SNP) | VAF 261/609 reads (43%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- ST6GAL2 | c.797G>C p.G266A | Missense Mutation (SNP) | VAF 77/161 reads (48%) | PolyPhen benign (0.224); called by muse, mutect2, varscan2
- STK32A | c.256T>A p.L86M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2
- STRBP | c.1348del p.A450Qfs*15 | Frame Shift Del (DEL) | VAF 34/77 reads (44%) | called by mutect2, pindel, varscan2
- SUGT1 | c.847T>C p.Y283H (on ENST00000343788 / NM_001130912.3; = p.Y251H on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1657G>C p.A553P | Missense Mutation (SNP) | VAF 349/427 reads (82%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.3235C>A p.Q1079K (on ENST00000367255 / NM_182961.4; = p.Q1086K on NM_033071.3) | Missense Mutation (SNP) | VAF 163/188 reads (87%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SYNJ2 | c.3110G>T p.G1037V | Missense Mutation (SNP) | VAF 114/136 reads (84%) | SIFT tolerated (0.12); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SYT13 | c.1061C>G p.P354R | Missense Mutation (SNP) | VAF 189/373 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYT9 | c.291G>T p.E97D | Missense Mutation (SNP) | VAF 147/371 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAF1L | c.2032G>T p.G678C | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF1L | c.1524G>T p.Q508H | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- TBC1D2 | c.1464G>T p.K488N | Missense Mutation (SNP) | VAF 138/260 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TBR1 | c.1947G>T p.E649D | Missense Mutation (SNP) | VAF 134/528 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TBX3 | c.796A>T p.S266C (on ENST00000257566 / NM_016569.4; = p.S246C on NM_005996.4) | Missense Mutation (SNP) | VAF 150/369 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCEAL2 | c.459del p.Y153* | Frame Shift Del (DEL) | VAF 70/102 reads (69%) | called by mutect2, pindel, varscan2
- TCEAL5 | c.288_299del p.E97_P100del | In Frame Del (DEL) | VAF 18/120 reads (15%) | called by mutect2, pindel
- TCTEX1D2 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- TDRD12 | c.1198G>T p.G400C | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- TDRD15 | c.5449T>A p.Y1817N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- TENT5D | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 54/60 reads (90%) | SIFT tolerated (0.17); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TERT | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 29/492 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- TESK1 | c.378C>A p.H126Q | Missense Mutation (SNP) | VAF 163/366 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TET1 | c.5608T>G p.C1870G | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX13C | c.565_584del p.E189Ffs*16 | Frame Shift Del (DEL) | VAF 132/197 reads (67%) | called by mutect2, pindel, varscan2
- TG | c.3065T>A p.L1022Q | Missense Mutation (SNP) | VAF 217/492 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
477 further variants in this file (82 protein-altering or splice-affecting, 248 silent, 147 other) are not listed here.
